Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3989, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3989-01A (Primary Tumor).

Diagnosis:

2. Hemicolectomy preparation with a moderately differentiated adenocarcinoma of the colon ascendens with infiltration of the pericolic fatty tissue. Eight lymph node metastases in total (28 lymph nodes examined).

Tumor classification: adenocarcinoma G2 pT3 N2 (8/30¹) L0 V0 R0.

¹ Though the text above says '28'.

Source: NCI Genomic Data Commons file f8e05fcc-ebf5-48b1-a993-27bbeaded453 (TCGA-AA-3989.7988769F-3450-4938-974F-A492C0122E9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).